Gene-level copy-number profile of specimen HCM-BROD-0954-C34-85A from HCMI case HCM-BROD-0954-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 66.3 years (24,222 days).
Specimen HCM-BROD-0954-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c123c0c6-2ba9-41a0-a554-9eb40a67805f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0954-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,258 have no estimate.
https://portal.gdc.cancer.gov/files/fa60d45d-f39f-43f9-a589-21464e40920b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 746; copy number 2: 17,034; copy number 3: 28,959; copy number 4: 9,805; copy number 5: 921; copy number 6: 745; copy number 7: 36; copy number 8: 51; copy number 9: 11; copy number 10: 41; copy number 11: 2; copy number 12: 12; copy number 13: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 155 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:121,451,541–121,451,967, 1 gene, copy number 7: TUBB4BP5.
- chr14:27,612,577–28,490,362, 5 genes, copy number 7–8 (within-gene range 6–8): LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3.
- chr14:28,726,675–29,500,460, 15 genes, copy number 7–8 (within-gene range 4–8): FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P, AL133166.1, AL158058.1, AL158058.2.
- chr14:33,924,227–36,679,362, 75 genes, copy number 8–13 (within-gene range 6–13) (broad region; genes not listed).
- chr14:38,738,155–39,183,220, 13 genes, copy number 7: LINC00639, AL132994.1, Y_RNA, SEC23A, AL109628.1, SEC23A-AS1, PPIAP4, GEMIN2, TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN.
- chr14:47,760,995–47,802,201, 3 genes, copy number 9: MIR548Y, LINC00648, AL121576.1.
- chr14:52,730,166–52,952,864, 9 genes, copy number 7–10 (within-gene range 7–11): STYX, GNPNAT1, AL139317.3, AL139317.5, AL139317.1, AL139317.2, FERMT2, AL139317.4, AL352979.4.
- chr14:54,842,008–56,117,990, 31 genes, copy number 7–10 (within-gene range 6–10): GCH1, RNU6ATAC9P, MIR4308, FDPSP3, WDHD1, RPSAP13, SOCS4, MAPK1IP1L, LGALS3, DLGAP5, AL139316.1, AL158801.4, COX5AP1, AL158801.2, Metazoa_SRP, CHMP4BP1, AL158801.3, ATG14, HMGN1P1, TBPL2, RPL21P6, KTN1-AS1, RPL7AP4, ABI1P1, KTN1, Y_RNA, AL355773.1, RPL13AP3, LINC00520, AL163952.1, AL138995.1.
- chr15:21,927,657–21,946,641, 1 gene, copy number 11: NF1P2.
- chr18:39,841,174–39,924,840, 2 genes, copy number 7: LINC01901, LINC01902.

Autosomal genes at a single copy (total copy number 1): 746. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
